Gene-level copy-number profile of tumor specimen ALCH-B786-TTP1-A from ALCHEMIST case ALCH-B786, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.4 years (26,441 days).
Specimen ALCH-B786-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dac0ef03-8045-4bf5-a129-2afb532d0748.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B786-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/cb4ddf9c-516e-473b-89b2-c31c3c44abc4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 177; copy number 1: 3,240; copy number 2: 54,476; copy number 3: 363; copy number 4: 126; copy number 5: 14; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 177 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,009,982–91,859,481, 89 genes (within-gene range 0–2) (broad region; genes not listed).
- chr3:130,034,553–130,055,920, 2 genes: OR7E21P, AC083906.4.
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr11:54,591,480–54,603,998, 2 genes: OR4C50P, OR4C46.
- chr19:24,098,425–24,163,425, 3 genes (within-gene range 0–1): BNIP3P40, AC073534.2, AC073534.1.
- chr21:7,744,962–13,120,807, 74 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,087,351–242,175,634, 5 genes, copy number 5–7: AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr6:35,607,628–35,652,856, 3 genes, copy number 5: AL033519.2, AL033519.5, AL033519.1.
- chr15:92,819,540–93,027,996, 4 genes, copy number 5 (within-gene range 2–5): CHASERR, AC013394.1, CHD2, MIR3175.
- chr20:49,632,945–49,713,878, 1 gene, copy number 5: B4GALT5.
- chr20:50,292,709–50,321,342, 2 genes, copy number 5: LINC01270, LINC01271.

Autosomal genes at a single copy (total copy number 1): 1,407. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
